Somatic mutation profile of tumor specimen TCGA-AX-A06L-01A (aliquot TCGA-AX-A06L-01A-11D-A122-09) from TCGA case TCGA-AX-A06L, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G1; Age at diagnosis: 63.8 years (23,294 days).
Specimen TCGA-AX-A06L-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 77bf2562-3840-425b-80c8-ed4bcea91297.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AX-A06L-10A (Blood Derived Normal), aliquot TCGA-AX-A06L-10A-01D-A122-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c701e897-f629-46da-8b46-40938cd6dd15

The open-access MAF lists 44 somatic variants for this specimen: 33 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 10, Frame Shift Ins 3, Splice Site 2, In Frame Del 1, Nonsense Mutation 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.104T>G p.I35S | Missense Mutation (SNP) | VAF 15/66 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV62687967, COSV62691314, COSV62693017; called by muse, mutect2
- PTEN | c.210-2A>G p.X70_splice | Splice Site (SNP) | VAF 25/73 reads (34%) | hotspot (GDC flag); catalogued as rs1564828914, CD109151, COSV64302273; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BCAN | c.2450C>T p.P817L | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.137); catalogued as rs762033515, COSV61256821; called by muse, mutect2, varscan2
- CCDC30 | c.1579C>T p.R527C (on ENST00000340612; = p.R484C on NM_001080850.3) | Missense Mutation (SNP) | VAF 129/379 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs981201493, COSV59608319; called by muse, mutect2, varscan2
- CELSR1 | c.953C>T p.T318M | Missense Mutation (SNP) | VAF 62/156 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as rs763953734, COSV53095967; called by muse, mutect2, varscan2
- CFAP47 | c.517G>T p.G173C | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV99935856; called by muse, mutect2
- CHD4 | c.2591G>A p.R864Q (on ENST00000357008 / NM_001363606.2; = p.R877Q on NM_001273.5) | Missense Mutation (SNP) | VAF 55/134 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58900818; called by muse, mutect2, varscan2
- CHRNB4 | c.730G>A p.V244M | Missense Mutation (SNP) | VAF 306/792 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.847); catalogued as rs368785360; called by muse, mutect2, varscan2
- DISP1 | c.3989C>T p.T1330M | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.057); catalogued as rs140229487; called by muse, mutect2, varscan2
- EIF2S3 | c.7G>A p.G3S | Missense Mutation (SNP) | VAF 115/280 reads (41%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV53407517; called by muse, mutect2, varscan2
- EXOC3 | c.169G>A p.G57R | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.72); catalogued as rs575184002, COSV59268003; called by muse, mutect2, varscan2
- GBF1 | c.5501C>T p.A1834V (on ENST00000369983 / NM_001377137.1; = p.A1833V on NM_004193.3) | Missense Mutation (SNP) | VAF 59/171 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.999); catalogued as rs770517190, COSV64144592; called by muse, mutect2, varscan2
- GPATCH8 | c.2113G>T p.G705W | Missense Mutation (SNP) | VAF 224/563 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.887); catalogued as COSV59196579; called by muse, mutect2, varscan2
- GTDC1 | c.1262G>T p.R421I (on ENST00000344850 / NM_001354361.1; = p.R336I on NM_024659.6 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 64/167 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54001369; called by muse, mutect2, varscan2
- MAP7D2 | c.591C>G p.D197E | Missense Mutation (SNP) | VAF 100/264 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.029); catalogued as COSV65527793, COSV65530326; called by muse, mutect2
- NFKB2 | c.1757C>T p.A586V | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV50052369; called by muse, mutect2, varscan2
- OSGEPL1 | c.36dup p.K13* | Frame Shift Ins (INS) | VAF 28/68 reads (41%) | catalogued as rs750679212; called by mutect2, varscan2
- PCDHB16 | c.1142C>T p.T381M | Missense Mutation (SNP) | VAF 121/307 reads (39%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.073); catalogued as COSV53367603; called by muse, mutect2, varscan2
- POLA1 | c.2797G>T p.D933Y | Missense Mutation (SNP) | VAF 12/331 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV100985635, COSV100985798; called by muse, mutect2
- PTEN | c.514del p.R172Gfs*11 | Frame Shift Del (DEL) | VAF 62/220 reads (28%) | catalogued as COSV64290267, COSV64302274; called by mutect2, pindel, varscan2
- RHOBTB3 | c.1000G>A p.A334T | Missense Mutation (SNP) | VAF 76/240 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as rs769589148, COSV66101230; called by muse, mutect2, varscan2
- SF3B1 | c.658C>A p.Q220K | Missense Mutation (SNP) | VAF 45/120 reads (38%) | SIFT tolerated (0.96); PolyPhen benign (0.001); catalogued as COSV59221682; called by muse, mutect2, varscan2
- SH2D3C | c.556-2A>C p.X186_splice (on ENST00000314830 / NM_170600.3; = p.X29_splice on NM_005489.4) | Splice Site (SNP) | VAF 81/211 reads (38%) | catalogued as COSV59127328; called by muse, mutect2, varscan2
- SNTG1 | c.254C>G p.S85* | Nonsense Mutation (SNP) | VAF 63/164 reads (38%) | catalogued as COSV52460165, COSV52469125; called by muse, mutect2, varscan2
- SSTR5 | c.689C>T p.A230V | Missense Mutation (SNP) | VAF 148/386 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.15); catalogued as rs371339888, COSV53513902, COSV99559473; called by muse, mutect2
- TGDS | c.853A>G p.M285V | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV54301962; called by muse, mutect2, varscan2
- TM2D1 | c.10G>T p.A4S | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV53906228, COSV53906985, COSV53908391; called by muse, mutect2, varscan2
- TRIM9 | c.1649T>A p.I550N | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.018); catalogued as COSV53621965; called by muse, mutect2, varscan2
- UBR1 | c.2018G>T p.S673I | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as COSV51933951; called by muse, mutect2, varscan2
- WDCP | c.758T>G p.V253G | Missense Mutation (SNP) | VAF 51/136 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as COSV54593180; called by muse, mutect2, varscan2
- ARID1A | c.3666dup p.R1223Afs*5 | Frame Shift Ins (INS) | VAF 162/282 reads (57%) | called by mutect2, pindel, varscan2
- PIK3R1 | c.1736_1742delinsC p.Q579_L581delinsP (on ENST00000521381 / NM_181523.3; = p.Q309_L311delinsP on NM_181504.4) | In Frame Del (DEL) | VAF 90/330 reads (27%) | called by pindel, varscan2*
- SCN8A | c.4361_4367dup p.N1457Hfs*11 | Frame Shift Ins (INS) | VAF 124/350 reads (35%) | called by mutect2, varscan2
- FRG2C | c.837G>T p.L279= | Silent (SNP) | VAF 122/936 reads (13%) | called by muse, mutect2
- GPT | c.651C>T p.D217= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as COSV52954217; called by muse, mutect2, varscan2
- KCNQ2 | c.2358G>A p.T786= (on ENST00000359125 / NM_172107.4; = p.T758= on NM_004518.6) | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as rs559610397, COSV60539429; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- KLHL11 | c.630C>T p.S210= | Silent (SNP) | VAF 43/109 reads (39%) | catalogued as rs1555622416, COSV59862690; called by muse, mutect2, varscan2
- KMT2D | c.6324G>A p.P2108= | Silent (SNP) | VAF 20/48 reads (42%) | catalogued as rs373945547; called by muse, mutect2, varscan2
- PCDHB15 | c.444T>C p.L148= | Silent (SNP) | VAF 52/144 reads (36%) | catalogued as COSV51199464; called by muse, mutect2, varscan2
- PCDHB6 | c.1533G>T p.L511= | Silent (SNP) | VAF 85/230 reads (37%) | catalogued as COSV50712004; called by muse, varscan2
- STOML1 | c.999T>C p.T333= | Silent (SNP) | VAF 48/115 reads (42%) | catalogued as COSV57552140; called by muse, mutect2, varscan2
- TGIF2 | c.447G>A p.G149= | Silent (SNP) | VAF 27/63 reads (43%) | catalogued as COSV65836740; called by muse, mutect2, varscan2
- ZBTB16 | c.1722C>T p.Y574= | Silent (SNP) | VAF 62/162 reads (38%) | catalogued as rs753518284, COSV60088679; called by muse, mutect2, varscan2
- MIR513B | n.82G>T | RNA (SNP) | VAF 49/205 reads (24%) | called by muse, mutect2, varscan2
